Gene-level copy-number profile of specimen HCM-SANG-1313-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1313-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1313-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9ef0b83-c4ae-41fe-8f87-65d96f3b27a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1313-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/261d3933-e603-4cd8-abe6-776a6465564e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 374; copy number 1: 79; copy number 2: 8,252; copy number 3: 30,323; copy number 4: 12,767; copy number 5: 3,581; copy number 6: 2,959; copy number 7: 400; copy number 8: 45; copy number 9: 18; copy number 10: 35; copy number 11: 11; copy number 12: 47; copy number 14: 1; copy number 15: 18; copy number 22: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 577 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,913,982–90,367,699, 33 genes, copy number 7–9: IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr7:37,032–7,535,873, 179 genes, copy number 7 (broad region; genes not listed).
- chr7:14,814,131–15,842,360, 10 genes, copy number 7: AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.1.
- chr7:125,229,579–125,346,197, 4 genes, copy number 7: AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr13:31,063,306–31,162,388, 2 genes, copy number 7: WDR95P, HSPH1.
- chr13:33,180,401–33,281,584, 1 gene, copy number 7 (within-gene range 6–7): STARD13-AS.
- chr13:34,910,545–34,928,076, 2 genes, copy number 7: Metazoa_SRP, AL138690.1.
- chr13:65,309,855–65,310,953, 1 gene, copy number 8: STARP1.
- chr13:70,459,464–71,914,178, 10 genes, copy number 7–9: RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21.
- chr13:72,586,680–74,259,976, 22 genes, copy number 8: AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402.
- chr13:74,434,538–74,565,445, 2 genes, copy number 8 (within-gene range 4–8): AL355390.2, LINC00347.
- chr17:39,401,793–39,451,272, 2 genes, copy number 22 (within-gene range 4–22): AC005288.1, MED1.
- chr17:59,619,689–60,666,280, 45 genes, copy number 12 (within-gene range 4–12): CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr20:30,214,765–32,335,011, 65 genes, copy number 10–15 (broad region; genes not listed).
- chr20:33,407,957–33,650,036, 2 genes, copy number 7: SNTA1, CBFA2T2.
- chr20:36,507,702–36,573,391, 3 genes, copy number 7 (within-gene range 6–7): DLGAP4-AS1, MYL9, Metazoa_SRP.
- chr20:37,571,103–37,623,119, 3 genes, copy number 7: LINC01746, GLRXP1, LINC00489.
- chr20:38,033,725–38,260,772, 6 genes, copy number 7 (within-gene range 6–7): RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2.
- chr20:38,977,711–39,224,748, 2 genes, copy number 7: NPM1P19, LINC01734.
- chr20:41,402,083–41,618,384, 3 genes, copy number 7 (within-gene range 6–7): CHD6, AL031667.2, AL031667.3.
- chr20:43,189,998–43,466,046, 9 genes, copy number 7: AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6.
- chr20:43,894,720–44,069,616, 2 genes, copy number 7 (within-gene range 6–7): LINC01728, TOX2.
- chr20:45,174,902–45,209,768, 2 genes, copy number 7: PI3, SEMG1.
- chr20:45,293,445–45,708,817, 31 genes, copy number 7: MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617.
- chr20:45,791,954–46,022,073, 19 genes, copy number 7 (within-gene range 6–7): DNTTIP1, UBE2C, TNNC2, SNX21, ACOT8, Metazoa_SRP, ZSWIM3, ZSWIM1, SPATA25, NEURL2, CTSA, AL008726.1, PLTP, AL162458.1, PCIF1, ZNF335, FTLP1, MMP9, SLC12A5-AS1.
- chr20:48,324,812–48,384,895, 3 genes, copy number 7: AL121888.1, LINC00494, AL137078.1.
- chr20:48,821,688–49,568,137, 19 genes, copy number 7 (within-gene range 6–7): AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS.
- chr20:49,721,949–49,794,914, 3 genes, copy number 7: RN7SL197P, SNRPFP1, RNU6-919P.
- chr20:50,184,598–50,283,250, 3 genes, copy number 7: CEBPB-AS1, CEBPB, PELATON.
- chr20:52,051,663–52,204,308, 3 genes, copy number 7: ZFP64, AL109984.1, ERP29P1.
- chr20:53,799,823–54,173,986, 6 genes, copy number 7: AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1.
- chr20:56,392,371–56,460,387, 2 genes, copy number 7 (within-gene range 6–7): CSTF1, CASS4.
- chr20:58,097,267–58,451,101, 6 genes, copy number 7: AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB.
- chr20:58,634,772–59,364,773, 29 genes, copy number 7: LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2.
- chr20:59,577,509–59,933,655, 4 genes, copy number 7: PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2.
- chr20:60,414,396–60,564,625, 3 genes, copy number 7: MTCO2P1, MIR4533, MIR548AG2.
- chr20:62,122,461–62,308,862, 8 genes, copy number 7 (within-gene range 6–7): LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1.
- chr20:62,796,473–62,841,159, 4 genes, copy number 7 (within-gene range 6–7): MRGBP, OGFR-AS1, OGFR, COL9A3.
- chr20:63,587,602–63,657,682, 3 genes, copy number 7: GMEB2, MHENCR, STMN3.
- chr20:63,939,829–64,033,100, 7 genes, copy number 7: UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6.

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
